Somatic mutation profile of tumor specimen BA2640D (aliquot aq-BA2640D) from BEATAML1.0 case 2245, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.7 years (19,258 days).
Specimen BA2640D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eecde568-53b6-4b18-b4e1-46fd50ba899a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2706D (Solid Tissue Normal), aliquot aq-BA2706D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e03282b-37d7-441d-a10e-5bfab78f64a8

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Intron 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SRSF2 | c.284_307del p.P95_R102del | In Frame Del (DEL) | VAF 20/52 reads (38%) | hotspot (GDC flag); catalogued as rs766200080; called by mutect2, varscan2
- KDM5C | c.4442G>A p.R1481K | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as CD086101; called by muse, mutect2, varscan2
- MAZ | c.989A>C p.D330A | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as rs1468996543, COSV50715255; called by muse, mutect2
- MED13 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV101181340; called by muse, mutect2, varscan2
- NCKAP1L | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs180951280; called by muse, mutect2, varscan2
- TIAM1 | c.3654C>T p.D1218= | Splice Region (SNP) | VAF 18/32 reads (56%) | catalogued as rs375189386; called by muse, varscan2
- COL5A3 | c.2506G>A p.G836S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFCC1 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- NOS1 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPT1 | c.302G>T p.R101L (on ENST00000317459 / NM_001160393.1; = p.R52L on NM_031472.4) | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TSC22D1 | c.2070G>T p.Q690H | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- ZNF234 | c.1835A>C p.Q612P | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- GANC | c.1509G>A p.T503= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs961869883; called by mutect2, varscan2
- KMT2B | c.5886C>A p.G1962= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- NIBAN1 | c.732G>A p.L244= | Silent (SNP) | VAF 47/131 reads (36%) | called by muse, mutect2, varscan2
- AC004890.2 | n.1599+74C>A | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
- STXBP2 | c.902+27C>T | Intron (SNP) | VAF 40/93 reads (43%) | catalogued as rs1378303293; called by mutect2, varscan2
